Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A8CK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A8CK-01A (Primary Tumor).

[page 1 of 4]
CLL ICD-O-3
Adenocarcinoma, acinar 8140/3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
Jt 11/27/13

DOB:

Sex:

Episode Results

1. - HIST
2. - VOLUMETRIC
3. - SYNOPSIS

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

HISTOPATHOLOGY REPORT

CLINICAL NOTES :

Ca prostate, T2b/T3, G19.

MACROSCOPIC :

Specimen 1: Labelled pt details. A prostate and attached seminal vesicles 45 x 40 x 40 mm and weighing 32 g.

Block designation:

Right apex: A to C. Left apex: D to E

Right base: F to H. Left base: I to K

Apex to base, right: L to O. Apex to base, left: P to S. P19

MICROSCOPIC :

The sections show bilateral, multifocal, peripheral and transition zone prostate adenocarcinoma. The index tumour involves the left mid/base, peripheral zone type, Gleason patterns **4+5=9**, with multifocal perineural invasion. The index tumour includes foci of direct and perineural extraprostatic extension at the left base posteriorly up to 7 mm; the overlying inked pathological margin is clear.

There is a separate multifocal, bilateral transition zone adenocarcinoma, extending from apex to base anteriorly, Gleason patterns **3+4(40%)=7**. There are foci of extraprostatic extension at the

[page 2 of 4]
right apex 5 mm with an overlying positive pathological margin 2 mm, and the left apex 1 mm with an overlying positive pathological margin 0.5 mm. The tumour at the margins is Gleason pattern 3 and shows diathermy change.

There are separate foci of peripheral zone carcinoma bilaterally, Gleason patterns $3+4(5\%)=7$ and $3+3=6$. No lymphovascular invasion is identified. All remaining inked pathological margins and seminal vesicles are clear.

CONCLUSION:

Radical prostatectomy: Bilateral, multifocal prostate adenocarcinoma; index tumour left-sided, Gleason patterns $4+5=9$ with extraprostatic extension left base up to 7 mm; separate multifocal transition zone adenocarcinoma, Gleason patterns $3+4(40\%)=7$ with foci of extraprostatic extension right apex 5 mm, left apex 1 mm and overlying positive pathological margins right apex 2 mm, left apex 0.5 mm; seminal vesicles clear; pT3a.

Reported by:

All Rights Reserved.

Email:

[page 3 of 4]
Episode Results

Patient Details

DOB:

Sex:

Episode Results

1. - HIST
2. - VOLUMETRIC
3. - SYNOPSIS

Doctor Details

Requesting Doctor:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

SYNOPTIC REPORT: CARCINOMA OF PROSTATE

Specimen type : Radical prostatectomy

Tumour type: Index tumour: adenocarcinoma nos

Other tumour foci: adenocarcinoma nos

Gleason score: Index tumour: 4+5=9 (peripheral zone type)

Other tumour foci: 3+4(40%)=7, 3+4(5%)=7, 3+3=6 (transition and peripheral zone types)

Site: Bilateral (see volumetric analysis)

Unifocal/Multifocal : Multifocal

Perineural invasion : Present; multifocal

Lymphovascular invasion : Not identified

Extraprostatic extension : Present, left base up to 7 mm, right apex 5 mm, left apex 1 mm

Seminal vesicle involvement : Not identified

Pathological resection margin status : Positive right apex 2 mm, left apex 0.5 mm (diathermy change)

Presence of PIN : Minimal

[page 4 of 4]
Lymph nodes: Not taken

Tumour Volume:

Peripheral Zone: 3.5cc

Transition Zone: 3.9cc

Pathologic stage: pT3a

Reported by:

Rights Reserved.

Email:

Source: NCI Genomic Data Commons file 32832a54-886c-45f0-8a55-1444b92d3291 (TCGA-J9-A8CK.D47D0C55-D871-44F3-A851-BD610FD7BA30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).